Surgical pathology report (de-identified scan), TCGA case TCGA-GN-A4U8, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Roswell, specimen TCGA-GN-A4U8-06A (Metastatic).

[page 1 of 4]
SPECIMEN(S):

A. LEFT AXILLARY CONTENTS

CLINICAL HISTORY:

Lymphadenopathy left axilla

PRE-OPERATIVE DIAGNOSIS:

None Given

ICD-0-3
Melanoma, NOS 8720/3
Site: lymph node, axilla C77.3
hw
10/10/12

DIAGNOSIS:

LEFT AXILLARY CONTENTS, EXCISION:

- ONE OUT OF FIFTY ONE LYMPH NODES IS POSITIVE FOR METASTATIC

MELANOMA, MICROMETASTASIS, WITH EXTRA-NODAL EXTENSION. (1/51)

Comment:

Immunostains performed on the block A25 and reported in the table below support the above diagnosis.

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

Material: Block A25

Population: Tumor Cells

Stain/Marker:

Result:

Comment:

[page 2 of 4]
S-100

Positive

A103,MELAN-A

Positive

The interpretation of the above immunohistochemistry stain or stains is guided by published results in the medical literature, provided package information from the manufacturer and by internal review of staining performance and assay validation within

The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristic determined by

They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Special stains and/or immunohistochemical stains were performed with appropriately stained positive and/or negative controls.

GROSS DESCRIPTION:

A. LEFT AXILLARY CONTENTS

Received fresh labeled with the patient's identification and designated "left axillary contents" is a portion of fibroadipose tissue measuring 21 x 17 x 3.5 cm. Multiple possible lymph nodes are identified ranging from 0.3 x 0.3 x 0.2 cm up to 4.5 x 3.6 x 2.1 cm. A portion of the largest lymph node is submitted for tissue procurement. Cassettes are submitted as follows:

A1: 4 possible lymph nodes

A2: 4 possible lymph nodes

A3: 5 possible lymph nodes

A4: 5 possible lymph nodes

[page 3 of 4]
A5: 3 possible lymph nodes
A6: 5 possible lymph nodes
A7: One bisected lymph node
A8: One bisected lymph node
A9: One bisected lymph node
A10: One bisected lymph node
A11: One bisected lymph node
A12: One bisected lymph node
A13: One bisected lymph node
A14: One bisected lymph node
A15: One bisected lymph node
A16: One bisected lymph node
A17: One bisected lymph node
A18: One bisected lymph node
A19: One bisected lymph node
A20: 2 possible lymph nodes
A21: 3 possible lymph nodes
A22: 4 possible lymph nodes
A23-A24: One lymph node, sectioned
A25: One representative section, largest lymph node

ADDENDUM:

This addendum is issued to correct the typo error in the report, it should read:
"MACROmetastasis".

The diagnosis remains unchanged.

[page 4 of 4]
Addendum:

This addendum is issued to report the size of the tumor in the involve lymph node: the metastatic tumor is 3.1cm in greatest dimension, measured on the slide.

1/10/12

Source: NCI Genomic Data Commons file 7fa07b32-dee5-44f6-a2e0-f221dbe4175c (TCGA-GN-A4U8.DD76E9F7-E667-4D5A-840E-980679252584.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).